Somatic mutation profile of tumor specimen ALCH-B3IC-TTP1-A (aliquot ALCH-B3IC-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3IC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,937 days).
Specimen ALCH-B3IC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89ad61e5-a204-4510-b8c1-eb097a0c4529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IC-NB1-A (Blood Derived Normal), aliquot ALCH-B3IC-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c32c34f2-ab7e-4d4a-a006-33d51804a10f

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Nonsense Mutation 3, Frame Shift Del 3, RNA 3, 3'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 156/555 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FSD1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs765462502, COSV55698843; called by muse, mutect2, varscan2
- GPAA1 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs1483302330; called by muse, mutect2
- GRID1 | c.1116C>T p.G372= | Splice Region (SNP) | VAF 18/133 reads (14%) | catalogued as rs1268066697, COSV60032984; called by muse, mutect2, varscan2
- KIF1C | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs760757050, COSV100297035; called by muse, mutect2, varscan2
- LGI4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1326647337, COSV59533060; called by muse, mutect2, varscan2
- MGA | c.8864del p.P2955Lfs*15 (on ENST00000219905 / NM_001164273.1; = p.P2746Lfs*15 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 17/124 reads (14%) | catalogued as COSV54956394; called by mutect2, pindel, varscan2
- PRDM14 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV52575769; called by muse, mutect2, varscan2
- SENP2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); catalogued as COSV56194079; called by muse, mutect2, varscan2
- ABTB2 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- AGAP9 | c.1598C>A p.S533* | Nonsense Mutation (SNP) | VAF 57/1123 reads (5%) | called by muse, mutect2
- ASXL3 | c.5019C>G p.H1673Q | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT14 | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.247); called by muse, mutect2
- GOLGB1 | c.7069G>T p.E2357* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- H3C10 | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- IGLV3-12 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- KMT2D | c.6302C>T p.A2101V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OSMR | c.705A>T p.K235N | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- OTOF | c.5051A>G p.E1684G (on ENST00000272371 / NM_194248.3; = p.E917G on NM_004802.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCDHB12 | c.728A>T p.E243V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- PKHD1 | c.10643A>G p.Q3548R | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2
- TMEM120B | c.840_855del p.F280Lfs*35 | Frame Shift Del (DEL) | VAF 19/157 reads (12%) | called by mutect2, pindel
- USP46 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- VPS13A | c.1361_1365del p.L454Rfs*6 | Frame Shift Del (DEL) | VAF 38/351 reads (11%) | called by mutect2, pindel, varscan2
- AWAT1 | c.738T>A p.R246= | Silent (SNP) | VAF 55/476 reads (12%) | called by muse, mutect2, varscan2
- BCKDHB | c.663C>T p.A221= | Silent (SNP) | VAF 53/491 reads (11%) | called by muse, mutect2, varscan2
- LGR5 | c.2418G>T p.L806= | Silent (SNP) | VAF 37/376 reads (10%) | catalogued as rs151206916, COSV57005785; called by muse, mutect2, varscan2
- LRFN1 | c.825C>T p.C275= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as rs766080025; called by muse, mutect2, varscan2
- MAPRE1 | c.603C>T p.N201= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as rs142439935; called by muse, mutect2
- MUC16 | c.43464C>T p.N14488= | Silent (SNP) | VAF 25/211 reads (12%) | catalogued as rs556135322, COSV101109479; called by muse, mutect2, varscan2
- PXDN | c.1452G>T p.S484= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as rs80053278, COSV53229892; called by muse, mutect2, varscan2
- SPATA31E1 | c.3459C>T p.S1153= | Silent (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- TENM3 | c.6606G>A p.T2202= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs140050384, COSV69298812; called by muse, mutect2, varscan2
- AFF3 | chr2:100105829 G>C | 5'Flank (SNP) | VAF 42/276 reads (15%) | catalogued as rs1425655010; called by muse, mutect2, varscan2
- AGAP12P | n.1599C>A | RNA (SNP) | VAF 17/132 reads (13%) | called by muse, varscan2
- C9orf62 | n.314C>A | RNA (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- OR3A4P | n.1310G>T | RNA (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- TMEM135 | c.*4685G>A | 3'UTR (SNP) | VAF 86/626 reads (14%) | called by muse, mutect2, varscan2
- ZNF99 | c.*2865A>C | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
